Gene-level copy-number profile of tumor specimen TCGA-AC-A5XU-01A from TCGA case TCGA-AC-A5XU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.4 years (27,191 days).
Specimen TCGA-AC-A5XU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.513f5d19-3ff2-436a-adeb-817f9ac828d6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A5XU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e40f3883-d78b-4e11-92e9-e9d69ca1b6e1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 570; copy number 2: 11,495; copy number 3: 21,711; copy number 4: 21,432; copy number 5: 2,653; copy number 6: 429; copy number 7: 597; copy number 8: 316; copy number 9: 166; copy number 10: 99; copy number 11: 16; copy number 12: 23; copy number 13: 21; copy number 15: 152; copy number 16: 18; copy number 17: 39; copy number 28: 5; copy number 30: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A5XU-01A-11D-A28A-01): tumor purity 0.78, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:39,030,436–39,237,293, 7 genes: AC010605.1, ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1.
- chr19:50,927,079–51,403,650, 50 genes (within-gene range 0–8): PPIAP59, KLK5, AC011483.2, KLK6, AC011483.3, AC011483.1, KLK7, KLK8, AC011473.4, KLK9, KLK10, AC011473.2, KLK11, KLK12, AC011473.3, AC011473.1, KLK13, KLK14, CTU1, SIGLEC18P, SIGLEC9, AC063977.2, SIGLEC7, AC063977.1, AC063977.5, AC063977.6, SIGLEC17P, SIGLEC20P, AC063977.4, SIGLEC21P, MIR8074, SIGLEC22P, CD33, SIGLECL1, AC063977.3, LINC01872, SIGLEC24P, IGLON5, VSIG10L, AC008750.2, AC008750.3, ETFB, AC008750.7, AC008750.4, CLDND2, NKG7, LIM2, C19orf84, AC008750.6, NIFKP6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,456 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:36,308,245–38,275,558, 52 genes, copy number 8–17 (within-gene range 3–17): AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2.
- chr8:94,533,628–95,811,254, 34 genes, copy number 7 (within-gene range 3–7): AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2, C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1, RNU6-690P.
- chr8:97,241,742–98,159,835, 20 genes, copy number 10–16 (within-gene range 2–16): AP003115.1, TSPYL5, SNORD3H, AP002982.1, AP002982.2, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1.
- chr8:104,478,539–104,589,024, 4 genes, copy number 12: AP002847.1, MIR548A3, LRP12, NDUFA5P2.
- chr8:105,142,860–105,288,365, 3 genes, copy number 13: AC021546.1, TMCC1P1, AC041039.1.
- chr8:114,791,653–117,176,714, 18 genes, copy number 10–30: CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P.
- chr8:122,671,291–122,974,510, 7 genes, copy number 8 (within-gene range 1–8): AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1.
- chr8:124,823,702–125,091,819, 9 genes, copy number 10 (within-gene range 5–10): LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1.
- chr8:126,325,454–127,742,951, 22 genes, copy number 10–13: AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:131,308,545–132,111,159, 7 genes, copy number 8: AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1.
- chr8:133,191,039–135,299,719, 38 genes, copy number 7–10 (within-gene range 2–10): CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591.
- chr11:69,294,151–69,926,813, 17 genes, copy number 10: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2.
- chr13:80,115,733–89,280,240, 68 genes, copy number 7–8 (broad region; genes not listed).
- chr16:78,525,189–78,553,296, 3 genes, copy number 13: AC046158.4, AC046158.2, AC046158.3.
- chr17:27,456,470–27,626,438, 1 gene, copy number 7 (within-gene range 3–7): KSR1.
- chr17:27,612,588–30,702,775, 183 genes, copy number 7 (broad region; genes not listed).
- chr17:30,724,982–30,727,564, 2 genes, copy number 7: AC127024.7, AC127024.3.
- chr17:68,152,776–68,422,731, 9 genes, copy number 7 (within-gene range 4–7): RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6.
- chr17:69,961,568–70,135,608, 5 genes, copy number 8: LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16.
- chr17:74,203,582–75,406,162, 66 genes, copy number 9 (broad region; genes not listed).
- chr18:55,589,904–57,029,811, 18 genes, copy number 8–10 (within-gene range 4–10): AC022031.2, RPL21P126, LINC01415, AC022031.1, AC027584.1, LINC01416, AC009271.1, AC006305.1, AC009271.2, LINC01905, AC006305.2, SNORA73, LINC01539, AC006305.3, TXNL1, WDR7, Y_RNA, AC012301.1.
- chr18:57,961,231–59,158,832, 32 genes, copy number 7: LINC01897, HMGN1P30, NEDD4L, AC107896.1, AC090236.2, AC090236.1, AC105105.2, MIR122HG, MIR122, MIR3591, AC105105.4, ALPK2, AC105105.3, AC105105.1, AC104971.2, SNORA108, RPL9P31, AC104971.3, AC104971.1, MALT1, AC104365.1, MRPL37P1, AC104365.3, AC104365.2, RNU6-219P, LINC01926, U8, ZNF532, RNU2-69P, OACYLP, AC040963.1, SEC11C.
- chr18:60,329,190–65,652,053, 66 genes, copy number 9–16 (within-gene range 5–16) (broad region; genes not listed).
- chr18:65,917,782–67,899,619, 17 genes, copy number 7–13: AC023394.1, PRPF19P1, CDH19, RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2.
- chr18:68,237,100–69,055,189, 15 genes, copy number 7 (within-gene range 5–7): AC005909.2, LINC01912, AC022968.1, AC005909.1, AKR1B10P2, MTL3P, TMX3, CCDC102B, AC040896.1, AC022035.1, RNU6-39P, SDHCP1, AC096708.2, AC096708.3, AC096708.1.
- chr19:11,925,075–12,724,011, 65 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr19:19,708,965–21,720,035, 99 genes, copy number 7 (broad region; genes not listed).
- chr19:22,902,538–23,291,017, 21 genes, copy number 9: AC022145.1, AC022145.2, ZNF728, BNIP3P36, LINC01859, LINC01858, AC074135.2, AC074135.1, ZNF730, BNIP3P37, AC124856.1, SNX6P1, AC092329.2, ZNF724, AC092329.3, BNIP3P38, IPO5P1, AC092329.1, AC092329.4, VN1R90P, VN1R91P.
- chr19:32,581,190–33,589,688, 40 genes, copy number 7: PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131.
- chr19:37,411,155–38,370,943, 38 genes, copy number 15: ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1.
- chr19:39,254,916–40,465,764, 76 genes, copy number 7–9 (broad region; genes not listed).
- chr19:51,410,020–52,367,778, 68 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr19:53,107,879–55,519,099, 239 genes, copy number 7–28 (within-gene range 4–28) (broad region; genes not listed).
- chr19:56,354,493–57,222,846, 40 genes, copy number 8: AC006116.8, ZNF542P, ZNF582, AC006116.9, SLC25A36P1, AC006116.4, ZNF582-AS1, ZNF583, ZNF667, ZNF667-AS1, AC004696.2, AC004696.1, ZNF471, AC005498.1, AC005498.2, ZFP28, AC005498.3, ZNF470, SIGLEC31P, ZNF71, ZIM2-AS1, SMIM17, ZNF835, AC006115.2, OR5AH1P, ZIM2, AC006115.1, PEG3, MIMT1, AC004792.1, AC044792.1, RPL7AP69, AC025588.4, USP29, ZIM3, AC025588.2, AC025588.3, DUXA, AC025588.1, ZNF264.
- chr19:57,803,841–58,397,079, 54 genes, copy number 8–12: ZNF552, AC010522.1, ZNF587B, FKBP1AP1, ZNF814, ZNF587, AC010326.3, AC010326.4, AC010326.2, ZNF417, ZNF418, ZNF256, AC010326.1, C19orf18, ZNF606, AC008969.1, VN2R19P, AC008969.2, ZSCAN1, LETM1P2, HNRNPDLP4, ZNF135, RN7SL526P, ZSCAN18, ZNF329, AC008751.1, AC008751.3, AC008751.2, ZNF274, RPS15AP36, AC020915.3, ZNF544, AC020915.4, AC020915.2, AC020915.1, ZNF8, ZNF8-ERVK3-1, ERVK3-1, AC010642.2, AC010642.1, ZSCAN22, MIR6806, A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225.

Autosomal genes at a single copy (total copy number 1): 570. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
